CPTAC case C3L-02354 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/01db2fd5-6443-4ed8-8318-3ef4f9012450

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 55.5 years (20,260 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G1; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 1,749 days (4.8 years); Progression or recurrence: yes; Days to recurrence: 1,294 days (3.5 years); Days to last follow up: 1,749 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.1 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 13; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 670 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,050 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,421 days (3.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,294 days (3.5 years).
- Days to follow up: 1,421 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,749 days (4.8 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 327.

Other clinical attributes
- Weight: 80 kg; Height: 165 cm; BMI: 29.38.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02354-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 299 mg.
- Sample C3L-02354-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 372 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02354-22: Section location: Anterior and Posterior; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-02354-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 266 mg.
- Sample C3L-02354-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02354-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
